MMRF case MMRF_2191 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/afafdba0-3a41-4879-9fe2-f2c10ae05c7b

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.1 years (21,569 days); ISS stage: II; Days to last known disease status: 889 days (2.4 years); Days to last follow up: 889 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 379 days (1.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 268 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 287 days; Days to treatment end: 352 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 568 days (1.6 years); Days to treatment end: 694 days (1.9 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 581 days (1.6 years); Days to treatment end: 689 days (1.9 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 731 days (2.0 years); Days to treatment end: 731 days (2.0 years).
   Treatment given: Therapeutic agents: Daratumumab + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 868 days (2.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 869 days (2.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 3.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1163 mg/dL; Immunoglobulin G 43.9 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.99 µg/mL; Hemoglobin 5.83 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 9.2 g/dL; Glucose 6.22 mmol/L.
- Day 78 (ECOG 1): M Protein 1.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 25 mg/dL; Immunoglobulin G 20.2 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 4.35 mmol/L.
- Day 182 (ECOG 1): M Protein 1.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.4 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 4.57 mmol/L.
- Day 233: M Protein 1.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.932 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.17 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.26 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.17 mmol/L.
- Day 350 (ECOG 2): M Protein 1.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.817 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.04 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.92 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Glucose 6.44 mmol/L.
- Day 448 (ECOG 2): M Protein 1.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.7 mg/dL; Immunoglobulin G 19.2 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.25 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 11.6 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 6.05 mmol/L.
- Day 567: Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.6 mg/dL; Immunoglobulin G 24.6 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 8 g/dL; Glucose 5.28 mmol/L.
- Day 644: Serum Free Immunoglobulin Light Chain, Kappa 2.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.2 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.29 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5.23 mmol/L.
- Day 805: Hemoglobin 7.07 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 196 ×10⁹/L.
- Day 889 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.5 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 4.62 mmol/L.

Other clinical attributes
- Day 1: Weight: 117 kg; Height: 185 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2191_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2191_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
